Somatic mutation profile of tumor specimen TCGA-CW-5591-01A (aliquot TCGA-CW-5591-01A-01D-1534-10) from TCGA case TCGA-CW-5591, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 56.7 years (20,712 days).
Specimen TCGA-CW-5591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4eabba0-6047-445f-af93-4f2b91a68838.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-5591-11A (Solid Tissue Normal), aliquot TCGA-CW-5591-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e201aeb-3956-4818-b0d2-a91a59bb0fa3

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 27, Silent 7, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 24/103 reads (23%) | catalogued as rs5030825, CM941391, COSV56548498; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.4428G>C p.Q1476H (on ENST00000372530 / NM_001198934.2; = p.Q1448H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV55089318; called by muse, mutect2
- AREL1 | c.1742C>T p.T581I | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62666815; called by muse, mutect2, varscan2
- B3GAT1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs896978571, COSV56998192; called by muse, mutect2, varscan2
- CACNA2D1 | c.1508G>T p.R503L | Missense Mutation (SNP) | VAF 145/700 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs758561622, COSV62382055; called by muse, mutect2, varscan2
- DIO2 | c.670G>T p.G224W | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV70444970, COSV70445363; called by muse, mutect2, varscan2
- DST | c.19454T>A p.L6485H (on ENST00000361203 / NM_001374722.1; = p.L4182H on NM_015548.5) | Missense Mutation (SNP) | VAF 143/523 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55021254; called by muse, mutect2, varscan2
- HSPA4 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 156/582 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV59182676; called by muse, mutect2, varscan2
- IMPA2 | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 97/453 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV52320029; called by muse, mutect2, varscan2
- KRT3 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 37/374 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV58816021; called by muse, mutect2
- LRRC14B | c.1049C>G p.T350S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV52049198; called by muse, mutect2, varscan2
- LTBR | c.165C>G p.H55Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.697); catalogued as COSV57439143; called by muse, mutect2, varscan2
- MMRN1 | c.3323C>T p.T1108M | Missense Mutation (SNP) | VAF 96/377 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764291894, COSV53338674; called by muse, mutect2, varscan2
- NFATC3 | c.797G>C p.R266T | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60474898; called by muse, mutect2
- NOS1 | c.1274A>T p.Q425L | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV57614709; called by muse, mutect2, varscan2
- PDE3B | c.3020G>C p.G1007A | Missense Mutation (SNP) | VAF 20/671 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV56385368; called by muse, mutect2
- PRSS48 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 108/399 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71613915; called by muse, mutect2, varscan2
- PUM3 | c.1164G>C p.K388N | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67396579; called by muse, varscan2
- RAP2B | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60257133; called by muse, mutect2
- RNF4 | c.50A>C p.Q17P | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as COSV58641563; called by muse, mutect2
- SENP8 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 27/96 reads (28%) | catalogued as COSV61768061; called by muse, mutect2, varscan2
- SETD2 | c.4920G>T p.W1640C | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57439612, COSV57440632; called by muse, mutect2, varscan2
- TANGO6 | c.3044T>G p.V1015G | Missense Mutation (SNP) | VAF 73/359 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99936153; called by muse, mutect2, varscan2
- TARBP1 | c.3869C>T p.A1290V | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50188256; called by muse, mutect2
- TCF7L2 | c.673G>T p.D225Y (on ENST00000355995 / NM_001367943.1; = p.D202Y on NM_030756.5) | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53342407; called by muse, mutect2, varscan2
- UPB1 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV58114144; called by muse, mutect2, varscan2
- ZNF169 | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as rs532233833, COSV61764890; called by muse, mutect2, varscan2
- ZNF445 | c.1698G>T p.K566N | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV68539023; called by muse, mutect2, varscan2
- ZNF98 | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1268487886, COSV63337364; called by muse, varscan2
- NLRP1 | c.977_978insG p.P327Tfs*56 | Frame Shift Ins (INS) | VAF 176/388 reads (45%) | called by mutect2, pindel*, varscan2*
- ADGRG3 | c.540C>A p.R180= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as COSV59651430; called by muse, mutect2, varscan2
- FLRT2 | c.747C>T p.L249= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV58140273; called by muse, mutect2, varscan2
- GPN3 | c.219C>A p.P73= | Silent (SNP) | VAF 62/429 reads (14%) | catalogued as COSV57401931; called by muse, mutect2, varscan2
- MLLT1 | c.1128G>A p.P376= | Silent (SNP) | VAF 232/519 reads (45%) | catalogued as rs753003626, COSV53131187; called by muse, mutect2, varscan2
- NKTR | c.2304T>G p.V768= | Silent (SNP) | VAF 34/153 reads (22%) | catalogued as COSV51772795; called by muse, mutect2, varscan2
- USP24 | c.684C>T p.L228= | Silent (SNP) | VAF 85/412 reads (21%) | catalogued as COSV53770237; called by muse, mutect2, varscan2
- ZSWIM2 | c.1545T>G p.P515= | Silent (SNP) | VAF 52/338 reads (15%) | catalogued as COSV54576348; called by muse, mutect2, varscan2
